CCDI case PBCSSW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/6b151e4e-aefa-4488-8a34-41584b41494f

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Granulosa cell tumor, juvenile: ICD-O-3 morphology code: 8622/1; Tissue or organ of origin: Ovary; Age at diagnosis: 12.4 years (4,520 days).

Biospecimens (3 samples)
- Sample 0DYKRL: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DYKS6: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DYKSF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
